Surgical pathology report (de-identified scan), TCGA case TCGA-EO-A3L0, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University Health Network, specimen TCGA-EO-A3L0-01A (Primary Tumor).

[page 1 of 4]
1CD-0-3
adenocarcinoma, endometrioid, NOS 8380/3
Site: Endometrium c54.1
12/21/11

Surgical Pathology Consultation Report

Specimen(s) Received

1. Omentum: biopsy
2. Hernia Sac
3. Uterus: Uterus, cervix, bilateral tubes & ovaries
4. Lymph node: Peri aortic lymph node
5. Lymph node: Left obturator
6. Lymph node: Right obturator

Diagnosis

1. Omentum:
- Negative for carcinoma
2. Hernia sac:
- Negative for carcinoma
3. Uterus, cervix, ovaries and fallopian tubes, bilateral:
- Uterus:
- ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, GRADE 3/3:
- infiltration of inner one half of myometrial thickness
- focal lymphovascular space involvement
- cervix - negative for carcinoma
- Other:
- adenomyosis
- Ovaries:
- Negative for carcinoma
- Fallopian tubes:
- Negative for carcinoma
4. Lymph nodes, para-aortic:
- Negative for carcinoma (2 lymph nodes)
5. Lymph nodes, left obturator:
- Negative for carcinoma (3 lymph nodes)
6. Lymph nodes, right obturator:
- Negative for carcinoma (8 lymph nodes)

Comment

Immunohistochemistry profile:

[page 2 of 4]
Surgical Pathology Consultation Report

ER, PR - focally positive
P53 - negative

Synoptic Data

Specimen:	Uterine corpus Cervix Right ovary Left ovary Right fallopian tube Left fallopian tube Omentum
Procedure:	Simple hysterectomy Bilateral salpingo-oophorectomy Omentectomy
Lymph Node Sampling:	Performed: Pelvic lymph nodes Performed: Para-aortic lymph nodes
Specimen Integrity:	Intact hysterectomy specimen
Tumor Site:	Other: fundus
Tumor Size:	Greatest dimension: 5.6 cm
Histologic Type:	Endometrioid adenocarcinoma, not otherwise characterized
Histologic Grade:	FIGO grade 3
Myometrial Invasion:	Present Myometrial thickness: 28 mm Less than 50% myometrial invasion
Involvement of Cervix:	Not involved
Extent of Involvement of Other Organs:	Right ovary not involved Left ovary not involved Right fallopian tube not involved Left fallopian tube not involved Vagina not applicable Right parametrium not applicable Left parametrium not applicable Omentum not involved Rectal wall not applicable Bladder wall not applicable Pelvic wall not applicable Bladder mucosa and/or bowel mucosa not applicable Uninvolved by invasive carcinoma
Margins:	Present
Lymph-Vascular Invasion:	Not applicable
TNM Descriptors:	pT1a (IA): Tumor limited to endometrium or invades less than 1/2 of the myometrium
Primary Tumor (pT):	pN0: No regional lymph node metastasis
Regional Lymph Nodes (pN):	Pelvic lymph nodes examined: 11 Pelvic lymph nodes involved: 0 Para-aortic lymph nodes examined: 2 Para-aortic lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	None identified

Electronically verified by:

[page 3 of 4]
Surgical Pathology Consultation Report

Clinical History
endometrial ca

Gross Description

1. The specimen labeled with the patient's name and as "Omentum: Biopsy". It consists of a large unoriented segment of omentum measuring 35.0 x 11.5 x 2.0 cm; weighing 171.5 g (fresh). Gross sections of the specimen appear homogeneously yellow-tan, focally hemorrhagic and otherwise unremarkable. No distinct lesions or tumors are grossly identified.

1A-1E representative sections submitted

2. The specimen labeled with the patient's name and as "Hernia Sac". It consists of multiple unoriented pieces of yellow-tan, partly hemorrhagic, soft to firm tissue ranging in size from 2.3 x 0.8 x 0.5 cm up to 10.0 x 6.0 x 1.2 cm. Closer examination reveals that part of the specimen has a membranous appearance. The remainder of the specimen is otherwise unremarkable. No distinct lesions or tumors are grossly identified.

2A representative sections submitted

3. The specimen, labeled with the patient's name and as "Uterus: Uterus, cervix, bilateral tubes & ovaries". The specimen is received fresh and subsequently placed in 10% buffered formalin. It consists of a uterus with attached cervix, bilateral ovaries and fallopian tubes; weighing 148.0 g (fresh). The body of the uterus is uniform and measures 10.4 cm SI x 6.1 cm ML x 5.6 cm AP. The serosal surface is purplish-pink, focally hemorrhagic and smooth. The cervix has a maximum diameter of 2.5 cm. The cervical Os measures 0.7 cm in maximum diameter and has a "slit-like" shape. The uterus is bivalved. The endometrium is not a uniform thickness. The endometrial cavity is 95% occupied by a large, fungating, pale-tan tumor measuring 5.6 cm SI x 5.3 cm ML x 3.7 cm AP. The tumor shows gross invasion into the myometrium and is located 2.6 cm from the posterior exocervix, 2.5 cm from the anterior exocervix and 1.0 cm from the closest serosal surface (posterior aspect). The cut surface of the tumor appears homogeneously white-tan, solid in the center and friable towards the periphery. The myometrium is not of uniform thickness, ranging from 1.6 up to 2.8 cm. Cross sections reveal multiple intramural fibroids. The largest measuring 2.5 cm in diameter and is located within the anterior aspect of the uterus. Cut sections of the fibroids appear homogeneously white and firm, showing a typical whorled appearance. The endocervical canal measures 2.5 cm in length, is patent and shows small amounts of mucoid material. The cervix reveals multiple tiny Nabothian cysts, the largest measuring 0.2 cm in diameter. All of the Nabothian cysts are filled with clear gelatinous material. The right ovary measures 1.7 x 1.2 x 1.0 cm. The surface of the right ovary appears pale-tan and smooth. Cross sections show corpus albicans. The right fallopian tube measures 5.5 cm in length x 0.5 cm in diameter. The surface of the right fallopian tube appears purplish-pink and smooth. Cross sections appear pale-tan and grossly unremarkable. The left ovary measures 1.6 x 0.7 x 1.0 cm. The surface of the left ovary appears pale-tan and smooth. Cross sections show corpus albicans. The left fallopian tube measures 6.5 cm in length x 0.6 cm in diameter. The surface of the left fallopian tube appears purplish-pink and smooth, showing a few paratubular cysts; the largest measuring 0.4 cm in diameter (filled with white milky fluid). Cross sections appear pale-tan and grossly unremarkable. One section from each ovary/fallopian tube, as well as two pieces of endometrial tumor has been stored frozen. Representative sections are submitted as follows:

3A left fimbria, longitudinally trisected

3B sections of left fallopian tube, adjacent to tissue banking

3C remainder of left fallopian tube,

3D sections of left ovary, adjacent to tissue banking

3E-3F remainder of left ovary,

3G right fimbria, longitudinally trisected

3H sections of right fallopian tube, adjacent to tissue banking

3I remainder of right fallopian tube,

3J sections of right ovary, adjacent to tissue banking

3K-3L remainder of right ovary,

3M a full-thickness, transverse section of endo/myometrium with tumor (including some normal endometrium-adjacent to fundus), anterior aspect

3N-3O a full-thickness, transverse section of endo/myometrium with tumor (including largest fibroid) bisected, anterior aspect

3P-3Q a full length/full-thickness section of endo/myometrium with tumor (bisected), from endometrial cavity to exocervix, anterior aspect

3R-3S a full-thickness/ transverse section of endo/myometrium with tumor (including intramural fibroids; bisected), posterior aspect

3T-3U a full-thickness/ transverse section of endo/myometrium with tumor (bisected), posterior aspect (block 3U contains tumor with closest serosal surface)

[page 4 of 4]
Surgical Pathology Consultation Report

3V one full-thickness/ transverse section of normal endo/myometrium (adjacent to fundus), posterior aspect
3W-3X a full length/full-thickness section of endo/myometrium with tumor (bisected), from endometrial cavity to exocervix, posterior aspect

4. The specimen labeled with the patient's name and as "Lymph node: Peri-aortic lymph node" consists of a piece of fibroadipose tissue that measures 3.5 x 2.3 x 1.5 cm and contains two lymph nodes that measures 0.5 and 0.7 cm in greatest dimension. Representative sections are submitted as follows:

4A one lymph node

4B one bisected lymph node

5. The specimen labeled with the patient's name and as "Lymph node: Left obturator" consists of a piece of fibroadipose tissue that measures 4.9 x 2.7 x 1.5 cm and contains two lymph nodes that measures 1.9 and 2.9 cm in greatest dimension. Representative sections are submitted as follows:

5A one bisected lymph node

5B-5D one lymph node, serially sectioned and submitted in toto

6. The specimen labeled with the patient's name and as "Lymph node: Right obturator" consists of a piece of fibroadipose tissue that measures 5.0 x 3.9 x 1.5 cm and contains multiple lymph nodes that range from 0.3 to 1.9 cm. Representative sections are submitted as follows:

6A multiple lymph nodes

6B-6D one bisected lymph node, per block

Source: NCI Genomic Data Commons file 9e39360c-6865-4704-be16-1e03477c4a99 (TCGA-EO-A3L0.AD1F0EEC-20B6-416B-9728-BC103D2B3B87.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).